MMRF case MMRF_1963 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/22487ec3-002f-4d29-8ed7-fd1d1ecec22c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.3 years (23,470 days); ISS stage: III; Days to last known disease status: 305 days; Days to last follow up: 305 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 305.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.121 mg/dL; Immunoglobulin G 6.42 g/L; Immunoglobulin A 50.7 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 6.59 µg/mL; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 9.8 g/dL; Glucose 6.82 mmol/L.
- Day 70 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.824 mg/dL; Immunoglobulin G 5.69 g/L; Immunoglobulin A 1.65 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 4.57 mmol/L.

Other clinical attributes
- Day -5: Weight: 77 kg; Height: 181 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1963_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1963_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
